Somatic mutation profile of tumor specimen C3N-02274-01 (aliquot CPT0182380007) from CPTAC case C3N-02274, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.7 years (29,493 days).
Specimen C3N-02274-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63e885e5-b452-4f89-9feb-495b491a8080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02274-31 (Blood Derived Normal), aliquot CPT0182440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef1ae5ff-c60c-48ea-a0dc-954d92699899

The open-access MAF lists 1,753 somatic variants for this specimen: 1,176 protein-altering or splice-affecting, 336 silent, 241 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 797, Silent 336, Frame Shift Del 230, Intron 136, Frame Shift Ins 54, 3'UTR 36, Nonsense Mutation 31, Splice Site 25, RNA 22, 5'UTR 22, Splice Region 21, 5'Flank 18.

Variants (750 of 1,753; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMT | c.59del p.P20Rfs*76 | Frame Shift Del (DEL) | VAF 95/234 reads (41%) | catalogued as rs386833686, CD983450, COSV56469502; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- ARSA | c.302del p.G101Afs*7 | Frame Shift Del (DEL) | VAF 96/235 reads (41%) | catalogued as rs761606317, CM910050, CM990175; ClinVar: pathogenic; called by mutect2, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 111/575 reads (19%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 202/535 reads (38%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BAP1 | c.592del p.E198Rfs*33 | Frame Shift Del (DEL) | VAF 247/543 reads (45%) | catalogued as rs1205668341, CM1512191, COSV56241587; ClinVar: likely pathogenic; called by mutect2, varscan2
- CTCF | c.615_618del p.K206Pfs*15 | Frame Shift Del (DEL) | VAF 192/507 reads (38%) | catalogued as rs1555534147; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 72/175 reads (41%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBN1 | c.3444del p.N1149Tfs*13 | Frame Shift Del (DEL) | VAF 226/567 reads (40%) | catalogued as rs1555398551; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- GALNS | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 233/555 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123430, CM042061; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.2892dup p.G965Rfs*154 | Frame Shift Ins (INS) | VAF 71/194 reads (37%) | catalogued as rs794728462; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 46/166 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 72/198 reads (36%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R2 | c.1681A>G p.N561D | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1057519801, COSV55847533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 324/349 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 35/88 reads (40%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC12A6 | c.298del p.E100Nfs*6 (on ENST00000354181 / NM_001365088.1; = p.E49Nfs*6 on NM_005135.2) | Frame Shift Del (DEL) | VAF 127/369 reads (34%) | catalogued as rs1555384169; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.4177C>T p.R1393W | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs753160597, COSV57051858; called by muse, mutect2, varscan2
- ABCG1 | c.1076del p.G359Vfs*5 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs1569239566, CM138401; called by mutect2, pindel, varscan2
- AC008676.3 | c.635del p.G212Vfs*24 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | catalogued as rs748255153; called by mutect2, pindel, varscan2
- ACAD9 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 230/483 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768772818; called by muse, mutect2, varscan2
- ACAP1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1320406090; called by muse, mutect2, varscan2
- ACAP2 | c.2014G>A p.V672I | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1308798437, COSV58753071; called by muse, mutect2, varscan2
- ACE | c.1384dup p.I462Nfs*19 | Frame Shift Ins (INS) | VAF 189/502 reads (38%) | catalogued as rs1409924291; called by mutect2, pindel, varscan2
- ACER1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.042); catalogued as rs368764098; called by muse, mutect2, varscan2
- ACTG1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 223/517 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782049546; called by muse, mutect2, varscan2
- ACTN4 | c.1442+4C>T | Splice Region (SNP) | VAF 151/321 reads (47%) | catalogued as rs745380705; called by muse, mutect2, varscan2
- ADAM30 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs761418593, COSV101023998; called by muse, mutect2, varscan2
- ADCK5 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs1403533272; called by muse, mutect2, varscan2
- ADGRD2 | c.1896del p.P633Qfs*53 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs1309868534; called by mutect2, pindel, varscan2
- ADGRG2 | c.366del p.F122Lfs*21 (on ENST00000379869 / NM_001079858.3; = p.F119Lfs*21 on NM_005756.4) | Frame Shift Del (DEL) | VAF 57/150 reads (38%) | catalogued as COSV61341022; called by mutect2, pindel, varscan2
- AFMID | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372327612; called by muse, mutect2, varscan2
- AGPAT2 | c.410dup p.V138Rfs*10 | Frame Shift Ins (INS) | VAF 155/434 reads (36%) | catalogued as rs1181209658; called by mutect2, pindel, varscan2
- AKNA | c.4076C>T p.A1359V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs745385072, COSV56337466; called by muse, mutect2, varscan2
- AKR1C4 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs377735731; called by muse, mutect2, varscan2
- AL031777.2 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.022); catalogued as COSV61912377; called by muse, mutect2, varscan2
- ALDH3B1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs1409537532, COSV50289466; called by muse, mutect2, varscan2
- ALPG | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 106/517 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1407092457, COSV99779098; called by muse, mutect2
- ALPI | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 24/494 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs1413537643; called by muse, mutect2
- AMER1 | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs374879781; called by muse, mutect2, varscan2
- ANK1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 234/792 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs1292183193; called by muse, mutect2, varscan2
- ANKRD26 | c.3169G>C p.D1057H | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV65773914; called by muse, mutect2, varscan2
- ANKRD34B | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100103562; called by muse, mutect2, varscan2
- ANO2 | c.2168C>T p.P723L (on ENST00000356134 / NM_001278597.3; = p.P727L on NM_001278596.3) | Missense Mutation (SNP) | VAF 109/270 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV59030713; called by muse, mutect2, varscan2
- ANO8 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 128/249 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1374447962; called by muse, mutect2, varscan2
- AOX1 | c.1948G>A p.V650I | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs777309422, COSV101022123; called by muse, mutect2, varscan2
- AP1M1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225215606; called by muse, mutect2, varscan2
- AP2A2 | c.448del p.E150Rfs*7 | Frame Shift Del (DEL) | VAF 71/207 reads (34%) | catalogued as COSV59965868; called by mutect2, pindel, varscan2
- APBA3 | c.1290del p.P431Lfs*14 | Frame Shift Del (DEL) | VAF 142/349 reads (41%) | catalogued as rs760320645; called by mutect2, pindel, varscan2
- APOA1 | c.391_393del p.K131del | In Frame Del (DEL) | VAF 187/451 reads (41%) | catalogued as rs532489785; called by pindel, varscan2
- ARHGAP27 | c.2054G>T p.R685L (on ENST00000428638 / NM_001282290.1; = p.R344L on NM_199282.3) | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV65358128; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 94/247 reads (38%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ASAP1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100726899; called by muse, mutect2, varscan2
- ASH2L | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV51698843; called by muse, mutect2, varscan2
- ATP13A3 | c.3576G>C p.E1192D (on ENST00000645319 / NM_001367549.1; = p.E1162D on NM_024524.3) | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV55465140; called by muse, mutect2, varscan2
- ATP1A2 | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 148/607 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100767722; called by muse, mutect2, varscan2
- ATP1A4 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 98/503 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63627425; called by muse, mutect2, varscan2
- AVL9 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 72/146 reads (49%) | catalogued as COSV100594622; called by muse, mutect2, varscan2
- BAHCC1 | c.5462C>T p.T1821M | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs782463831, COSV57033577; called by muse, mutect2, varscan2
- BAZ1B | c.3955G>A p.A1319T | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs782367420; called by muse, mutect2, varscan2
- BBOF1 | c.746del p.N249Tfs*44 | Frame Shift Del (DEL) | VAF 44/139 reads (32%) | catalogued as rs747134194; called by mutect2, pindel, varscan2
- BCHE | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100012226; called by muse, mutect2, varscan2
- BIRC6 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 132/263 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.611); catalogued as rs909401890; called by muse, mutect2, varscan2
- BMF | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754316143; called by muse, mutect2, varscan2
- BRWD1 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60902727; called by muse, mutect2, varscan2
- BTBD8 | c.5096C>T p.T1699I (on ENST00000636805 / NM_001376131.1; = p.T1186I on NM_015237.4) | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1474488550; called by muse, mutect2, varscan2
- C19orf44 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs768812832; called by muse, mutect2, varscan2
- C19orf57 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs145142690; called by muse, mutect2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 186/445 reads (42%) | catalogued as rs781818365; called by mutect2, varscan2
- C1orf43 | c.578G>A p.R193Q (on ENST00000368521 / NM_001297718.2; = p.R159Q on NM_015449.4) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1016886052, COSV62965968; called by muse, mutect2, varscan2
- C2orf76 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs780592227, COSV58347061; called by muse, mutect2, varscan2
- C4BPB | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99700201; called by muse, mutect2, varscan2
- C5 | c.2839A>G p.R947G | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs752846952; called by muse, mutect2, varscan2
- C9orf72 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.281); catalogued as COSV101186527; called by muse, mutect2, varscan2
- CA7 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1411565415; called by muse, mutect2, varscan2
- CACNA1E | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 61/555 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100701577, COSV62391937, COSV62405729; called by muse, mutect2, varscan2
- CALCR | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs749750687; called by muse, mutect2, varscan2
- CAMK1G | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 180/842 reads (21%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs538751935, COSV50528294; called by muse, mutect2, varscan2
- CAMK2G | c.1573C>T p.R525C (on ENST00000423381 / NM_001367518.1; = p.R462C on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/326 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1348279182; called by muse, mutect2, varscan2
- CAPN5 | c.1204G>A p.A402T (on ENST00000456580; = p.A362T on NM_004055.5) | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs782466794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPER3 | c.198del p.F66Lfs*10 | Frame Shift Del (DEL) | VAF 132/394 reads (34%) | catalogued as CM110786; called by pindel, varscan2
- CATSPER4 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58794269; called by muse, mutect2, varscan2
- CCDC117 | c.234T>G p.D78E | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs118090380, COSV50770679; called by mutect2, varscan2
- CCDC22 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs782461322; called by muse, mutect2
- CCDC80 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs760359684; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 79/213 reads (37%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV55669164; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 117/276 reads (42%) | catalogued as rs773911500; called by mutect2, varscan2
- CDC42BPA | c.5126del p.P1709Qfs*56 (on ENST00000334218 / NM_001366019.2; = p.P1696Qfs*56 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 50/250 reads (20%) | catalogued as rs869029351; called by mutect2, pindel, varscan2
- CDH10 | c.1569A>T p.K523N | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1268349921, COSV52580120; called by muse, mutect2, varscan2
- CDH16 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 126/317 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs761898809; called by muse, mutect2, varscan2
- CDH2 | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 180/370 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52284491; called by muse, mutect2, varscan2
- CDH4 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.725); catalogued as rs767319878; called by muse, mutect2, varscan2
- CDK18 | c.1241C>T p.P414L (on ENST00000506784 / NM_212503.3; = p.P384L on NM_002596.4) | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs756053212; called by muse, mutect2, varscan2
- CDK7 | c.638del p.L213Cfs*10 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | catalogued as COSV99841953; called by mutect2, pindel, varscan2
- CDON | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745363657; ClinVar: uncertain significance; called by muse, mutect2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP85L | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs766038507, COSV100682520; called by muse, mutect2, varscan2
- CER1 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV66603942; called by muse, mutect2, varscan2
- CFAP69 | c.2061dup p.P688Tfs*5 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | catalogued as rs1275710203; called by mutect2, varscan2
- CHD4 | c.4114del p.R1372Vfs*61 (on ENST00000357008 / NM_001363606.2; = p.R1385Vfs*61 on NM_001273.5) | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | catalogued as COSV100538025; called by mutect2, pindel
- CHD7 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.055); catalogued as rs1480884503; called by muse, varscan2
- CHD7 | c.6272G>T p.W2091L | Missense Mutation (SNP) | VAF 141/615 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM109247; called by muse, mutect2, varscan2
- CHD8 | c.6562G>T p.G2188* (on ENST00000646647 / NM_001170629.2; = p.G1909* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 135/282 reads (48%) | catalogued as rs1555313059; called by muse, varscan2
- CHRM4 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 162/406 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63126496; called by muse, mutect2, varscan2
- CILK1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs901020533, COSV63153887; called by muse, mutect2, varscan2
- CILP2 | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402749786, COSV52280720; called by muse, mutect2, varscan2
- CLVS2 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.593); catalogued as rs140575101; called by muse, mutect2
- CNIH3 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 98/500 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs1365117505, COSV99685948; called by muse, varscan2
- CNTN2 | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 111/511 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745457520; called by muse, mutect2, varscan2
- COL5A3 | c.4241del p.P1414Rfs*46 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as COSV53410357; called by mutect2, pindel
- COL6A2 | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.801); catalogued as rs541785316, COSV56018266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2423-2A>G p.X808_splice | Splice Site (SNP) | VAF 239/543 reads (44%) | catalogued as rs113088824, CS050383; called by muse, mutect2, varscan2
- COMP | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 145/351 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.155); catalogued as rs1030626977; called by muse, mutect2, varscan2
- COPS5 | c.921-5del | Splice Region (DEL) | VAF 21/54 reads (39%) | catalogued as rs200155628; called by mutect2, varscan2
- COQ10B | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55837119; called by muse, mutect2, varscan2
- CORO7 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs759014697, COSV99227888; called by muse, mutect2, varscan2
- CPNE4 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 135/317 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs774125661; called by muse, mutect2, varscan2
- CRACD | c.1421C>G p.A474G | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.073); catalogued as rs1469240168, COSV99950244; called by muse, mutect2, varscan2
- CRAMP1 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as rs922905655; called by muse, mutect2, varscan2
- CRTC1 | c.1713dup p.S572Qfs*4 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | catalogued as rs769538822; called by mutect2, varscan2
- CSTF1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV53859461; called by muse, mutect2, varscan2
- CTAGE9 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1219185563, COSV100020584; called by mutect2, varscan2
- CTCF | c.2070del p.E691Sfs*30 | Frame Shift Del (DEL) | VAF 78/190 reads (41%) | catalogued as rs1400980130; called by mutect2, pindel, varscan2
- CTRB2 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs369978964; called by muse, mutect2, varscan2
- CUX1 | c.3547G>A p.V1183I | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs201799537, COSV99470537; called by muse, mutect2, varscan2
- CYC1 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778645997, COSV100010249; called by mutect2, varscan2
- CYSLTR1 | c.657del p.K219Nfs*3 | Frame Shift Del (DEL) | VAF 36/99 reads (36%) | catalogued as rs35745545; called by mutect2, pindel, varscan2
- DAPK1 | c.1134C>T p.H378= | Splice Region (SNP) | VAF 57/121 reads (47%) | catalogued as rs989375552; called by muse, mutect2, varscan2
- DDX42 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs139222190; called by muse, mutect2, varscan2
- DGKD | c.2587G>A p.A863T (on ENST00000264057 / NM_152879.3; = p.A819T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs370474844; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 74/175 reads (42%) | catalogued as rs373108427; called by mutect2, varscan2
- DHX9 | c.2647A>G p.I883V | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV62358389; called by muse, mutect2, varscan2
- DISC1 | c.1793-7G>A | Splice Region (SNP) | VAF 78/472 reads (17%) | catalogued as rs776995123; called by muse, mutect2, varscan2
- DISP2 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs150424497; called by muse, mutect2, varscan2
- DLC1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs148727515, COSV52324792; called by muse, mutect2
- DLGAP3 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1042168477; called by muse, mutect2, varscan2
- DNAH9 | c.12638C>T p.A4213V | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs769630167; called by muse, mutect2
- DNAJC6 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769674686; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOHH | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs988158405; called by muse, mutect2
- DOK5 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 123/286 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs780293083, COSV52819629; called by muse, mutect2, varscan2
- DOLK | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868232833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOLK | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 323/747 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); catalogued as rs766362741; called by muse, mutect2, varscan2
- DPEP2 | c.120dup p.R41Qfs*26 | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | catalogued as rs547189498; called by mutect2, varscan2
- DPPA5 | c.292+2T>C p.X98_splice | Splice Site (SNP) | VAF 63/135 reads (47%) | catalogued as COSV64875478; called by muse, mutect2, varscan2
- DSC1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs372768585; called by muse, mutect2, varscan2
- DVL3 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 58/503 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53049445; called by muse, mutect2, varscan2
- DYNC1I1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.74); catalogued as COSV100269581; called by muse, mutect2
- DYRK1A | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs754161665; called by muse, mutect2, varscan2
- ECHDC2 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.63); catalogued as rs140085217; called by muse, mutect2, varscan2
- EFNA4 | c.535dup p.D179Gfs*65 | Frame Shift Ins (INS) | VAF 50/230 reads (22%) | catalogued as rs754580525; called by mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 67/130 reads (52%) | catalogued as COSV99653876; called by mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- ENGASE | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs754147468; called by muse, mutect2, varscan2
- EPHA4 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 129/275 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs750370585, COSV56044278; called by muse, mutect2, varscan2
- EPHA4 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56045181; called by muse, varscan2
- EPHX1 | c.1124A>G p.K375R | Missense Mutation (SNP) | VAF 494/665 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs1274499840, COSV55300352; called by muse, varscan2
- EPPK1 | c.4739G>A p.G1580D | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs368225830; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 132/272 reads (49%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV1 | c.414dup p.T139Hfs*24 | Frame Shift Ins (INS) | VAF 90/236 reads (38%) | catalogued as rs769886672; called by mutect2, varscan2
- EVA1B | c.68-4G>A | Splice Region (SNP) | VAF 177/406 reads (44%) | catalogued as rs1203873908; called by muse, mutect2, varscan2
- FAM110C | c.233del p.P78Rfs*18 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as COSV59656666; called by mutect2, pindel, varscan2
- FAM133A | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59075355, COSV59076492; called by muse, mutect2, varscan2
- FAM83H | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 233/535 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs782640124; called by muse, mutect2, varscan2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs1566257864; called by mutect2, pindel, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 74/195 reads (38%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FLNC | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs754309921, COSV57953861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs539058927; called by muse, mutect2, varscan2
- FREM2 | c.3161C>T p.T1054I | Missense Mutation (SNP) | VAF 234/493 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV54835520, COSV99746098; called by muse, mutect2, varscan2
- FRY | c.6757A>G p.M2253V | Missense Mutation (SNP) | VAF 149/354 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773344773; called by muse, mutect2, varscan2
- FRZB | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV54554832; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FURIN | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as rs370641172; called by muse, mutect2, varscan2
- FUT7 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs748875579, COSV55797294; called by muse, mutect2, varscan2
- FZD8 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 176/408 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65967925; called by muse, mutect2, varscan2
- GAPDHS | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs202137889; called by muse, mutect2
- GAS8 | c.1141_1143del p.K381del | In Frame Del (DEL) | VAF 44/460 reads (10%) | catalogued as rs760468250; called by pindel, varscan2
- GCC1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs200011353, COSV100365493; called by muse, mutect2, varscan2
- GCNT1 | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs762732983; called by muse, mutect2, varscan2
- GGA3 | c.1870G>A p.V624M (on ENST00000537686 / NM_138619.4; = p.V591M on NM_014001.5) | Missense Mutation (SNP) | VAF 120/314 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762124045; called by muse, mutect2, varscan2
- GJA4 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 109/257 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs774261822, COSV60724746; called by muse, mutect2, varscan2
- GNPTAB | c.3610T>C p.Y1204H | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54779139; called by muse, mutect2
- GPAM | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs552284961, COSV100788353; called by muse, mutect2, varscan2
- GPBP1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.578); catalogued as rs747751138, COSV53312838; called by muse, mutect2, varscan2
- GPC6 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV65512253; called by muse, mutect2, varscan2
- GPC6 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as rs756656699, COSV65524625; called by muse, varscan2
- GPR182 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 57/161 reads (35%) | catalogued as rs575072551, COSV100267643; called by muse, mutect2, varscan2
- GRID2 | c.1415T>C p.I472T | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs753415901; called by muse, mutect2, varscan2
- GSE1 | c.1483_1485del p.E495del | In Frame Del (DEL) | VAF 72/173 reads (42%) | catalogued as rs758757723; called by pindel, varscan2
- GSX1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100262418; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 66/78 reads (85%) | catalogued as COSV54945907; called by mutect2, varscan2
- HAND2 | c.168dup p.D57Rfs*286 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs763941066; called by mutect2, pindel, varscan2
- HAUS5 | c.118del p.A40Lfs*39 | Frame Shift Del (DEL) | VAF 124/280 reads (44%) | catalogued as rs984276080; called by mutect2, varscan2
- HCN1 | c.2294A>G p.N765S | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV57515469; called by muse, mutect2, varscan2
- HDGFL1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1389488879, COSV57751074; called by mutect2, varscan2
- HIC2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs188340044; called by muse, mutect2, varscan2
- HMG20A | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 33/123 reads (27%) | catalogued as rs1263163087; called by muse, mutect2, varscan2
- HOXB13 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs140492479, COSV51706761; called by muse, mutect2, varscan2
- HROB | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1185919583; called by muse, mutect2, varscan2
- HS3ST2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 129/305 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV54462472; called by muse, mutect2, varscan2
- HTR3E | c.851C>T p.T284M (on ENST00000415389 / NM_001256613.1; = p.T299M on NM_182589.2) | Missense Mutation (SNP) | VAF 151/378 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776733163; called by muse, mutect2, varscan2
- HTT | c.120_122del p.P49del | In Frame Del (DEL) | VAF 92/312 reads (29%) | catalogued as rs780629353; called by pindel, varscan2
- IFIT1B | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1252215466; called by muse, mutect2, varscan2
- IGDCC4 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 133/334 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs753195920; called by muse, mutect2, varscan2
- IGFBPL1 | c.697del p.L233Cfs*26 | Frame Shift Del (DEL) | VAF 85/207 reads (41%) | catalogued as rs1161674646; called by mutect2, pindel, varscan2
- IGHV3-13 | c.306C>G p.N102K | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); catalogued as rs370967026; called by muse, mutect2
- IGLV3-27 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 161/424 reads (38%) | catalogued as rs751481735; called by mutect2, pindel, varscan2
- IGSF21 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.848); catalogued as rs760730875; called by muse, mutect2, varscan2
- IL31RA | c.1601del p.G534Efs*7 | Frame Shift Del (DEL) | VAF 165/445 reads (37%) | catalogued as rs1561123861; called by mutect2, pindel, varscan2
- IL4I1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs371422304, COSV55578869, COSV99680473; called by muse, mutect2, varscan2
- INHBC | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs149645850; called by muse, mutect2, varscan2
- INMT | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs372838601; called by muse, varscan2
- INO80D | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 125/314 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776202202, COSV104434934, COSV68960441; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 41/113 reads (36%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IRS2 | c.2174del p.G725Afs*102 | Frame Shift Del (DEL) | VAF 78/231 reads (34%) | catalogued as rs1394911868; called by mutect2, pindel, varscan2
- IRS4 | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.284); catalogued as rs763120943; called by muse, mutect2, varscan2
- IRX5 | c.805dup p.R269Pfs*187 | Frame Shift Ins (INS) | VAF 49/160 reads (31%) | catalogued as rs754238323; called by mutect2, varscan2
- ITGA1 | c.3166C>T p.R1056* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as rs1373668661; called by muse, mutect2, varscan2
- ITGB7 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752378256, COSV57240348; called by muse, mutect2, varscan2
- ITIH5 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs1341255668, COSV56902224, COSV56905066; called by muse, mutect2
- ITLN1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1211220200; called by muse, mutect2
- JAG1 | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM003440; called by muse, mutect2, varscan2
- JMY | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.338); catalogued as rs767652704; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs1206265094; called by mutect2, pindel
- KCNA5 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 149/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753084398, COSV52908167; called by muse, mutect2, varscan2
- KCNA5 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261317505; called by muse, mutect2, varscan2
- KCND2 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 86/173 reads (50%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.006); catalogued as COSV58570797; called by muse, mutect2, varscan2
- KCNG2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs769581960, COSV60267267; called by muse, mutect2, varscan2
- KCNG2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302111, COSV60269221; called by muse, mutect2, varscan2
- KCNK1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 167/716 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs147294916; called by muse, mutect2, varscan2
- KCTD19 | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1212254792; called by muse, mutect2, varscan2
- KDM1A | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as rs1363624048, COSV100752680; called by muse, mutect2, varscan2
- KIAA0825 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.092); catalogued as rs371747852; called by muse, mutect2, varscan2
- KIF1A | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1373179079, COSV57486101; called by muse, mutect2, varscan2
- KIF3C | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.129); catalogued as rs751824281, COSV53101248; called by muse, mutect2, varscan2
- KIF5A | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 241/574 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99673425; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 62/261 reads (24%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLF12 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs375091947; called by muse, mutect2, varscan2
- KLHDC7B | c.580del p.V194Wfs*52 (on ENST00000395676; = p.V835Wfs*52 on NM_138433.5) | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs1198090154; called by mutect2, pindel, varscan2
- KLHDC9 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1289103995; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 64/178 reads (36%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 151/335 reads (45%) | catalogued as rs753167272; called by mutect2, varscan2
- LAG3 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 200/465 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs150796252; called by muse, mutect2, varscan2
- LAMA4 | c.1445A>G p.N482S (on ENST00000230538 / NM_001105206.3; = p.N475S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/429 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs924678750; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as rs1311334991; called by mutect2, pindel, varscan2
- LPCAT3 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1035421832; called by muse, mutect2, varscan2
- LRRC3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1175165323, COSV52400444; called by muse, mutect2, varscan2
- LRRC58 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs200466593; called by muse, mutect2, varscan2
- LRRC66 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs777531737; called by muse, mutect2, varscan2
- LRRFIP1 | c.1405G>T p.G469W (on ENST00000392000 / NM_001137552.2; = p.G445W on NM_004735.4) | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs756687536; called by muse, mutect2, varscan2
- LRRIQ1 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1329005832; called by muse, mutect2, varscan2
- LRRN1 | c.783del p.V262Ffs*4 | Frame Shift Del (DEL) | VAF 74/187 reads (40%) | catalogued as COSV100076048; called by mutect2, pindel, varscan2
- LSP1 | c.322dup p.Q108Pfs*6 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | catalogued as rs752018434; called by mutect2, varscan2
- LSR | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs576659755, COSV61554739; called by muse, mutect2, varscan2
- MACROD1 | c.241del p.L81Wfs*9 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | catalogued as rs1423172365; called by mutect2, pindel, varscan2
- MAGEA4 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs866165760, COSV52343067; called by muse, mutect2, varscan2
- MAGEB18 | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1428267619; called by muse, mutect2, varscan2
- MAJIN | c.489A>C p.K163N | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV54164703; called by muse, mutect2, varscan2
- MAMSTR | c.353C>T p.A118V (on ENST00000318083 / NM_001130915.2; = p.A15V on NM_182574.2) | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs748807571; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as rs1215313075; called by mutect2, pindel
- MAST1 | c.4462C>T p.R1488C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV52242537; called by muse, mutect2, varscan2
- MCIDAS | c.120+2T>C p.X40_splice | Splice Site (SNP) | VAF 94/227 reads (41%) | catalogued as rs1414605352; called by muse, mutect2, varscan2
- MED16 | c.2603T>C p.L868P | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1216712336, COSV54129416; called by muse, mutect2, varscan2
- MED29 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs768176929; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEGF8 | c.3395A>G p.D1132G (on ENST00000251268 / NM_001271938.2; = p.D1065G on NM_001410.3) | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs1233037830; called by muse, mutect2, varscan2
- MFN2 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 178/400 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs760375604; called by muse, mutect2, varscan2
- MFSD6 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as rs921603349; called by muse, mutect2, varscan2
- MIA3 | c.503dup p.N168Kfs*3 | Frame Shift Ins (INS) | VAF 44/230 reads (19%) | catalogued as rs756037599; called by mutect2, varscan2
- MICALL2 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs572446052; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as COSV54098507; called by mutect2, pindel, varscan2
- MIEF1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 41/502 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1240480107; called by muse, mutect2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs751180035; called by mutect2, varscan2
- MLKL | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 112/201 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs55987292; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRPL9 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 86/402 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs993021086, COSV58619913; called by muse, mutect2, varscan2
- MS4A6A | c.651+5G>A | Splice Region (SNP) | VAF 40/273 reads (15%) | catalogued as rs780314709; called by muse, mutect2, varscan2
- MSH6 | c.118del p.A40Pfs*41 | Frame Shift Del (DEL) | VAF 117/348 reads (34%) | catalogued as COSV52287227; called by mutect2, pindel, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 48/98 reads (49%) | catalogued as rs537060918; called by mutect2, varscan2
- MUC4 | c.14705del p.N4902Tfs*8 (on ENST00000463781 / NM_018406.7; = p.N666Tfs*8 on NM_004532.6) | Frame Shift Del (DEL) | VAF 171/422 reads (41%) | catalogued as rs766716021; called by mutect2, varscan2
- MVP | c.2623del p.Q875Sfs*22 | Frame Shift Del (DEL) | VAF 60/146 reads (41%) | catalogued as COSV62422216; called by mutect2, pindel, varscan2
- MYBPC1 | c.1706G>A p.G569D (on ENST00000550270 / NM_206820.2; = p.G594D on NM_002465.4) | Missense Mutation (SNP) | VAF 161/388 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV62258518; called by muse, mutect2, varscan2
- MYH14 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); catalogued as rs942541070, COSV51814216; called by muse, mutect2, varscan2
- MYH7 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 290/620 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV62518092; called by muse, mutect2, varscan2
- MYO16 | c.4282G>A p.G1428R | Missense Mutation (SNP) | VAF 194/437 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as rs762084319; called by muse, mutect2, varscan2
- MYO1B | c.562+2_562+3del p.X188_splice | Splice Site (DEL) | VAF 52/166 reads (31%) | catalogued as rs1194534321; called by pindel, varscan2
- MYOF | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.938); catalogued as rs1235663636, COSV63709951; called by muse, mutect2, varscan2
- N4BP2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 101/188 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); catalogued as rs757831372, COSV54700746; called by muse, mutect2, varscan2
- NAP1L2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1273072621, COSV100999215; called by muse, mutect2, varscan2
- NCAPD3 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs745665288, COSV101596377; called by muse, mutect2, varscan2
- NDRG3 | c.392G>T p.S131I (on ENST00000349004 / NM_032013.4; = p.S119I on NM_022477.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100675366; called by muse, mutect2, varscan2
- NDUFAF1 | c.959A>C p.E320A | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs767139367; called by muse, mutect2, varscan2
- NEB | c.5183C>A p.A1728D | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.543); catalogued as COSV51118205; called by muse, mutect2, varscan2
- NECAB3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs1372801311; called by muse, mutect2, varscan2
- NEURL3 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs1430534734; called by muse, mutect2, varscan2
- NFATC4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.791); catalogued as COSV99151253; called by muse, mutect2, varscan2
- NFKBIL1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as rs373866765; called by muse, mutect2, varscan2
- NHLRC1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs201476733, COSV61481253; called by muse, mutect2, varscan2
- NLGN2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs139254633; called by muse, mutect2, varscan2
- NOCT | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs1234174123, COSV54935538; called by muse, mutect2, varscan2
- NOS3 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); catalogued as rs765572803, COSV52486913; called by muse, mutect2, varscan2
- NOTCH3 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 179/405 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747223569, COSV54640179; called by muse, mutect2, varscan2
- NPC1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868281893; called by muse, mutect2, varscan2
- NPEPL1 | c.833C>A p.P278Q | Missense Mutation (SNP) | VAF 168/391 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1193972912; called by muse, mutect2, varscan2
- NR4A3 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV58247219; called by muse, mutect2, varscan2
- NT5M | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1160420042; called by muse, mutect2
- NUP210 | c.4591G>T p.G1531* | Nonsense Mutation (SNP) | VAF 98/222 reads (44%) | catalogued as COSV54404501, COSV99596676; called by muse, mutect2, varscan2
- OBSCN | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 118/456 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs746510162, COSV52736057; called by muse, mutect2, varscan2
- OBSCN | c.16823C>T p.T5608I | Missense Mutation (SNP) | VAF 82/421 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs761707760; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OR10AD1 | c.549del p.I184* | Frame Shift Del (DEL) | VAF 88/238 reads (37%) | catalogued as rs748413148; called by mutect2, pindel, varscan2
- OR14A16 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs529772848; called by muse, mutect2, varscan2
- OSBPL6 | c.1621+3A>G | Splice Region (SNP) | VAF 77/208 reads (37%) | catalogued as rs1344924764; called by muse, mutect2, varscan2
- OTUD6A | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV57973403; called by muse, mutect2, varscan2
- OVCH2 | c.257G>A p.W86* | Nonsense Mutation (SNP) | VAF 41/77 reads (53%) | catalogued as rs753875594; called by muse, mutect2, varscan2
- P2RX1 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 256/616 reads (42%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.808); catalogued as COSV99844714; called by muse, mutect2, varscan2
- P2RY2 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs1006024348, COSV60777637; called by muse, varscan2
- P2RY2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.234); catalogued as COSV60777208; called by muse, varscan2
- P2RY6 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1170552649, COSV62936716; called by muse, mutect2, varscan2
- PAPLN | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763361180; called by muse, mutect2, varscan2
- PAPLN | c.2969T>C p.I990T (on ENST00000554301; = p.I963T on NM_173462.4) | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53715804; called by muse, mutect2, varscan2
- PAPPA2 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 123/627 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs766424114, COSV62779163; called by muse, mutect2, varscan2
- PAX5 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV63905321; called by mutect2, varscan2
- PCDHA1 | c.1409C>A p.P470Q | Missense Mutation (SNP) | VAF 383/800 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1028195735; called by muse, mutect2, varscan2
- PCDHA1 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 130/472 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as COSV65373699; called by muse, mutect2, varscan2
- PCDHA10 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV56474940; called by muse, mutect2, varscan2
- PCDHB11 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 294/733 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.149); catalogued as rs781984382, COSV61314833; called by muse, mutect2, varscan2
- PCDHB12 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 112/581 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs201301252; called by muse, mutect2, varscan2
- PCDHB14 | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 272/614 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53386224; called by muse, mutect2, varscan2
- PCDHGA12 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 138/293 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1473172175, COSV52753292; called by muse, mutect2, varscan2
- PCDHGA12 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV52759640; called by muse, mutect2, varscan2
- PCDHGA9 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as rs751580878; called by muse, mutect2, varscan2
- PCDHGB1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 204/507 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99536286; called by muse, mutect2, varscan2
- PCLO | c.4852del p.S1618Afs*40 | Frame Shift Del (DEL) | VAF 106/293 reads (36%) | catalogued as COSV61648330; called by mutect2, pindel, varscan2
- PCOLCE | c.1173del p.M392* | Frame Shift Del (DEL) | VAF 68/151 reads (45%) | catalogued as rs777844367; called by mutect2, varscan2
- PDZD2 | c.308dup p.K104Qfs*38 | Frame Shift Ins (INS) | VAF 166/374 reads (44%) | catalogued as rs750970663; called by mutect2, varscan2
- PER1 | c.3724G>A p.G1242S | Missense Mutation (SNP) | VAF 145/294 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs775363004; called by muse, mutect2, varscan2
- PGM2 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 146/323 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as rs1386437293; called by muse, mutect2, varscan2
- PHACTR2 | c.685del p.T229Qfs*47 | Frame Shift Del (DEL) | VAF 44/96 reads (46%) | catalogued as rs746858891; called by mutect2, varscan2
- PHF21B | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs369146125; called by muse, mutect2, varscan2
- PHKG1 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 109/183 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as rs774182485; called by muse, mutect2, varscan2
- PHLPP1 | c.4927G>A p.A1643T | Missense Mutation (SNP) | VAF 157/355 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53024714; called by muse, mutect2, varscan2
- PITPNM2 | c.3613C>T p.H1205Y | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.438); catalogued as rs1308409538, COSV54907015; called by muse, mutect2, varscan2
- PKHD1 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as rs139770251; called by muse, mutect2, varscan2
- PLCG2 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 192/449 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63867505; called by muse, mutect2, varscan2
- PLEKHG4 | c.2053_2054del p.L686Qfs*2 | Frame Shift Del (DEL) | VAF 216/640 reads (34%) | catalogued as rs1267636359; called by pindel, varscan2
- PLEKHG4 | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 206/504 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1394772459; called by muse, mutect2, varscan2
- PLN | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 141/365 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as rs754782171, CM1110160, CM1110161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLOD1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 205/471 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52143557; called by muse, mutect2, varscan2
- PLPP3 | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs765501405; called by muse, mutect2, varscan2
- PLPPR3 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs746621782, COSV62459000; called by muse, mutect2, varscan2
- PLXNA2 | c.3403A>G p.T1135A | Missense Mutation (SNP) | VAF 129/565 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1021321286; called by muse, mutect2, varscan2
- PM20D1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs373311318; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1344-1G>T p.X448_splice (on ENST00000611850; = p.X449_splice on NM_005396.5) | Splice Site (SNP) | VAF 66/151 reads (44%) | catalogued as COSV53945912; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POU3F4 | c.346del p.A116Pfs*26 | Frame Shift Del (DEL) | VAF 89/215 reads (41%) | catalogued as CM116309; called by mutect2, pindel, varscan2
- PPARA | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 173/436 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749814012, COSV53081740; called by muse, mutect2, varscan2
- PPP1R12C | c.1058_1060del p.K353del | In Frame Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs1301546955; called by pindel, varscan2
- PPP1R26 | c.3290del p.G1097Afs*57 | Frame Shift Del (DEL) | VAF 40/98 reads (41%) | catalogued as rs764146060; called by mutect2, pindel, varscan2
- PPP1R27 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 159/363 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290972876; called by muse, mutect2, varscan2
- PPP1R32 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs776792732; called by muse, mutect2, varscan2
- PPTC7 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs376388180; called by muse, mutect2, varscan2
- PRB1 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs1325986952; called by muse, mutect2
- PRDM14 | c.1540del p.E514Rfs*52 | Frame Shift Del (DEL) | VAF 48/135 reads (36%) | catalogued as COSV52571528; called by mutect2, pindel, varscan2
- PRDM15 | c.1959+2T>C p.X653_splice | Splice Site (SNP) | VAF 69/145 reads (48%) | catalogued as COSV54153712; called by muse, mutect2, varscan2
- PRDM9 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 154/358 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs762092212, COSV99690415; called by muse, mutect2, varscan2
- PRKAG1 | c.186del p.F62Lfs*4 | Frame Shift Del (DEL) | VAF 114/274 reads (42%) | catalogued as rs1565733883; called by mutect2, varscan2
- PRKD2 | c.2543G>T p.G848V | Missense Mutation (SNP) | VAF 111/293 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52190041; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs537061158; called by mutect2, varscan2
- PRRC2C | c.2587G>A p.D863N (on ENST00000367742; = p.D861N on NM_015172.4) | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs963494016; called by muse, mutect2, varscan2
- PRSS56 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs532343102; called by muse, mutect2, varscan2
- PSG4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs765839412; called by muse, mutect2, varscan2
- PSMA3 | c.478-3T>C | Splice Region (SNP) | VAF 89/183 reads (49%) | catalogued as rs768060406; called by muse, mutect2, varscan2
- PSMD1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 126/280 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV58082260; called by muse, mutect2, varscan2
- PSPC1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752466806, COSV58887542; called by muse, mutect2, varscan2
- PTPRC | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 152/1092 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs764517655; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 74/224 reads (33%) | catalogued as rs1179811215; called by mutect2, pindel, varscan2
- PTPRS | c.3112A>G p.K1038E | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV99509040; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 56/90 reads (62%) | catalogued as rs745353960; called by mutect2, pindel
- RALGPS2 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as rs754899009; called by muse, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 93/253 reads (37%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RAPGEF6 | c.3266G>A p.R1089K | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV57256278; called by muse, mutect2
- RASAL2 | c.2593A>G p.T865A | Missense Mutation (SNP) | VAF 98/442 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100862474; called by muse, mutect2, varscan2
- RASGRP2 | c.1479dup p.R494Afs*54 | Frame Shift Ins (INS) | VAF 136/310 reads (44%) | catalogued as rs774996406; called by mutect2, varscan2
- RAVER2 | c.2060del p.K687Rfs*15 (on ENST00000294428 / NM_001366165.1; = p.K674Rfs*15 on NM_018211.4) | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as COSV53805154; called by mutect2, pindel, varscan2
- RB1 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV57324793; called by muse, mutect2, varscan2
- RBM42 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs371819218; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as rs759247453; called by mutect2, varscan2
- RGMB | c.1123G>A p.D375N (on ENST00000513185 / NM_001366508.1; = p.D416N on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/295 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243693462; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIC1 | c.1262A>G p.Q421R | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV52605664; called by muse, mutect2, varscan2
- RMDN1 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs1351612964; called by muse, mutect2, varscan2
- ROS1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs140178288; called by mutect2, varscan2
- RP1L1 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 230/531 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs758393932, COSV66758516; called by muse, mutect2, varscan2
- RSPH4A | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.862); catalogued as rs761926509; called by muse, mutect2, varscan2
- RTF1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs202234112, COSV67477650, COSV67477723; called by muse, mutect2, varscan2
- RTL1 | c.2546A>G p.E849G | Missense Mutation (SNP) | VAF 111/258 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV101128568; called by muse, mutect2, varscan2
- RYR1 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 142/283 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs933347966, COSV100614977; called by muse, mutect2, varscan2
- SALL2 | c.1586dup p.G530Rfs*3 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | catalogued as rs755171367; called by mutect2, varscan2
- SATB1 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs761051718; called by muse, mutect2, varscan2
- SBNO1 | c.3461A>G p.E1154G (on ENST00000420886; = p.E1153G on NM_018183.5) | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV57344406; called by muse, mutect2, varscan2
- SCAF8 | c.3385C>T p.R1129* | Nonsense Mutation (SNP) | VAF 21/193 reads (11%) | catalogued as COSV65792102; called by muse, mutect2, varscan2
- SCNN1G | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 101/285 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100263785, COSV100263892; called by muse, mutect2, varscan2
- SCRIB | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs976171888; called by muse, mutect2, varscan2
- SCUBE2 | c.2616del p.K873Sfs*5 (on ENST00000649792 / NM_001367977.2; = p.K816Sfs*5 on NM_020974.3) | Frame Shift Del (DEL) | VAF 115/327 reads (35%) | catalogued as rs753114269; called by mutect2, pindel, varscan2
- SELP | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55252758; called by muse, mutect2, varscan2
- SEMA3G | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.8); catalogued as rs780165717; called by muse, mutect2, varscan2
- SERINC4 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs143808872; called by muse, mutect2, varscan2
- SETD1A | c.4174C>T p.R1392C | Missense Mutation (SNP) | VAF 112/219 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as rs897760166; called by muse, varscan2
- SFMBT2 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs202183517, COSV62812881; called by muse, mutect2, varscan2
- SFPQ | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779173588; called by muse, mutect2, varscan2
- SGCE | c.1106T>C p.L369P (on ENST00000647096; = p.L333P on NM_003919.3) | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs758035606; called by muse, mutect2, varscan2
- SH3D19 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs761177950, COSV58789872; called by muse, mutect2, varscan2
- SHROOM2 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.022); catalogued as rs374843987; called by muse, mutect2, varscan2
- SLC13A4 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62461333; called by muse, mutect2, varscan2
- SLC15A3 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs752295863; called by muse, mutect2
- SLC22A1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100266400; called by muse, mutect2, varscan2
- SLC22A5 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 166/315 reads (53%) | catalogued as CM1313385; called by muse, mutect2, varscan2
- SLC26A4 | c.1737_1739del p.N579del | In Frame Del (DEL) | VAF 88/228 reads (39%) | catalogued as rs776068119; called by pindel, varscan2
- SLC30A3 | c.1159del p.Q387Kfs*78 | Frame Shift Del (DEL) | VAF 75/206 reads (36%) | catalogued as rs747206800; called by mutect2, pindel, varscan2
- SLC38A4 | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1470148093; called by muse, mutect2, varscan2
- SLC39A4 | c.724A>G p.S242G (on ENST00000301305 / NM_001374839.1; = p.S217G on NM_017767.3) | Missense Mutation (SNP) | VAF 153/353 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs1364461479; called by muse, mutect2, varscan2
- SLC6A12 | c.1100T>C p.F367S | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62883878; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 60/141 reads (43%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC8B1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 121/325 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs148596267; called by muse, mutect2, varscan2
- SMYD3 | c.1208C>T p.T403I (on ENST00000490107 / NM_001375962.1; = p.T344I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/405 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs114883730; called by muse, mutect2, varscan2
- SNX13 | c.1161del p.F387Lfs*18 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | catalogued as rs749866112; called by mutect2, pindel, varscan2
- SOCS6 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750588082, COSV67545911; called by muse, mutect2, varscan2
- SORBS2 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 84/377 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs775539307, COSV53010932; called by muse, mutect2, varscan2
- SORCS1 | c.2849T>C p.M950T | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV53850636; called by muse, mutect2, varscan2
- SOS2 | c.2909A>G p.Q970R | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99365839; called by muse, varscan2
- SPOCD1 | c.3282del p.R1095Gfs*32 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs1455579753; called by mutect2, pindel, varscan2
- ST7L | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58308099; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 48/104 reads (46%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAG2 | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54360934; called by muse, mutect2, varscan2
- STARD9 | c.10409C>T p.A3470V | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs572085935; called by muse, mutect2, varscan2
- STARD9 | c.12916C>T p.R4306* | Nonsense Mutation (SNP) | VAF 75/169 reads (44%) | catalogued as rs971100428; called by muse, mutect2, varscan2
- STIL | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs771811631, COSV99680980; called by muse, mutect2
- STPG3 | c.226del p.Q76Rfs*11 | Frame Shift Del (DEL) | VAF 82/213 reads (38%) | catalogued as rs773395497; called by mutect2, varscan2
- STXBP5 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761281235; called by muse, mutect2, varscan2
- SYCP1 | c.2642del p.K881Rfs*21 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs776683356; called by mutect2, varscan2
- SYN1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as COSV55982021; called by muse, mutect2, varscan2
- SYNM | c.2523dup p.H842Afs*5 | Frame Shift Ins (INS) | VAF 78/224 reads (35%) | catalogued as rs1469394583; called by mutect2, pindel, varscan2
- SZT2 | c.7274del p.P2425Lfs*9 (on ENST00000634258 / NM_001365999.1; = p.P2368Lfs*9 on NM_015284.4) | Frame Shift Del (DEL) | VAF 43/104 reads (41%) | catalogued as COSV65175105; called by mutect2, pindel, varscan2
- TAF2 | c.1278-3del | Splice Region (DEL) | VAF 68/173 reads (39%) | catalogued as rs751147458; called by mutect2, varscan2
- TAS2R42 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1432785822; called by muse, mutect2, varscan2
- TBX15 | c.638T>C p.V213A (on ENST00000369429 / NM_001330677.2; = p.V107A on NM_152380.3) | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1163435668; called by muse, mutect2, varscan2
- TCHH | c.958_960del p.E320del | In Frame Del (DEL) | VAF 134/740 reads (18%) | catalogued as rs200970876; called by pindel, varscan2
- TESK1 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); catalogued as rs567466527; called by muse, mutect2, varscan2
- TEX49 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs992682587; called by muse, mutect2, varscan2
- TFAP2D | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs780638088, COSV50430124; called by muse, mutect2, varscan2
- TKFC | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1052145620; called by muse, mutect2, varscan2
- TLE1 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs756362994, COSV64719457; called by muse, mutect2, varscan2
- TLE2 | c.1013-2A>C p.X338_splice | Splice Site (SNP) | VAF 107/265 reads (40%) | catalogued as COSV53581046; called by muse, mutect2, varscan2
- TLN2 | c.5753G>A p.R1918H | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs757144126; called by muse, mutect2, varscan2
- TMEM104 | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1185689595, COSV59107867; called by muse, mutect2, varscan2
- TMEM44 | c.1192G>T p.G398W (on ENST00000392432 / NM_001166305.2; = p.G351W on NM_138399.5) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56447325; called by muse, mutect2
- TMEM9 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs778529248; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 92/234 reads (39%) | catalogued as rs770800449; called by mutect2, varscan2
- TNIP3 | c.434del p.N145Ifs*15 | Frame Shift Del (DEL) | VAF 92/228 reads (40%) | catalogued as rs1467769330; called by mutect2, varscan2
- TNK2 | c.2491del p.Q831Rfs*2 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV100361518; called by mutect2, pindel, varscan2
- TNRC18 | c.1775G>A p.S592N | Missense Mutation (SNP) | VAF 174/439 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1448951763; called by muse, mutect2, varscan2
- TNS2 | c.1977del p.K660Nfs*96 (on ENST00000314250 / NM_170754.4; = p.K670Nfs*96 on NM_015319.2) | Frame Shift Del (DEL) | VAF 71/161 reads (44%) | catalogued as rs1379053061; called by mutect2, pindel, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 60/151 reads (40%) | catalogued as rs758129598; called by mutect2, varscan2
- TOR3A | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 184/922 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs754219042, COSV61680869; called by muse, mutect2, varscan2
- TRIO | c.6716C>T p.T2239I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs375075483; called by muse, varscan2
- TRIO | c.7116del p.S2375Pfs*38 | Frame Shift Del (DEL) | VAF 43/120 reads (36%) | catalogued as rs1177359280, COSV59989953; called by pindel, varscan2
- TRIO | c.7480G>A p.A2494T | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.511); catalogued as rs765576014; called by muse, mutect2, varscan2
- TRPM2 | c.2139del p.K714Rfs*14 | Frame Shift Del (DEL) | VAF 63/164 reads (38%) | catalogued as rs1198514145; called by mutect2, pindel, varscan2
- TRPM2 | c.3873-1G>A p.X1291_splice | Splice Site (SNP) | VAF 51/106 reads (48%) | catalogued as rs776498849; called by muse, mutect2, varscan2
- TRPV3 | c.259del p.Q87Sfs*7 | Frame Shift Del (DEL) | VAF 81/222 reads (36%) | catalogued as rs911130511, COSV100027514; called by mutect2, pindel, varscan2
- TSPYL5 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100438886; called by muse, mutect2, varscan2
- TTC19 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 121/290 reads (42%) | catalogued as rs773904382; called by muse, mutect2, varscan2
- TTC3 | c.1769dup p.N590Kfs*11 | Frame Shift Ins (INS) | VAF 27/74 reads (36%) | catalogued as rs752525442; called by mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 44/75 reads (59%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC6 | c.2997del p.D1000Tfs*2 | Frame Shift Del (DEL) | VAF 45/122 reads (37%) | catalogued as rs767436917; called by mutect2, pindel, varscan2
- TULP4 | c.3064del p.V1022Wfs*2 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs752011727; called by mutect2, varscan2
- TYK2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs907669947, COSV53392986, COSV99314045; called by muse, mutect2, varscan2
- U2SURP | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.885); catalogued as rs749684244, COSV101204459; called by muse, mutect2, varscan2
- UNC79 | c.4787C>T p.P1596L (on ENST00000393151 / NM_001346218.2; = p.P1419L on NM_020818.5) | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs375279499; called by muse, mutect2, varscan2
- USP19 | c.1383G>A p.S461= | Splice Region (SNP) | VAF 25/54 reads (46%) | catalogued as rs774200886, COSV60047128; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 43/103 reads (42%) | catalogued as rs761528888; called by mutect2, varscan2
- VAMP2 | c.29dup p.A11Cfs*19 | Frame Shift Ins (INS) | VAF 64/142 reads (45%) | catalogued as rs774244975, COSV57183212; called by mutect2, varscan2
- VASH2 | c.451C>T p.R151* (on ENST00000517399 / NM_001301056.2; = p.R86* on NM_001136474.3) | Nonsense Mutation (SNP) | VAF 41/280 reads (15%) | catalogued as rs1221181181; called by muse, mutect2, varscan2
- VASN | c.1193C>A p.P398Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs368386504; called by muse, mutect2, varscan2
- VIPR2 | c.173_175del p.N58del | In Frame Del (DEL) | VAF 74/238 reads (31%) | catalogued as rs780279954; called by pindel, varscan2
- VPS13D | c.7834G>A p.V2612I | Missense Mutation (SNP) | VAF 180/450 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs139303925, COSV50668432; called by muse, mutect2, varscan2
- VWA7 | c.212del p.P71Lfs*34 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as rs1410246345, COSV100791785; called by mutect2, pindel, varscan2
- WDR76 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs373892287; called by muse, mutect2, varscan2
- WDR87 | c.7038del p.E2347Kfs*14 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs908903048; called by mutect2, pindel, varscan2
- WTAP | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV64330569; called by muse, mutect2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | catalogued as rs1403895317; called by mutect2, pindel, varscan2
- ZAN | c.240del p.Y81Tfs*96 | Frame Shift Del (DEL) | VAF 117/314 reads (37%) | catalogued as rs773398085, COSV61809202; called by mutect2, pindel, varscan2
- ZBTB16 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1439463569; called by muse, mutect2, varscan2
- ZBTB26 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419398602, COSV65403564; called by muse, mutect2, varscan2
- ZBTB7B | c.392C>T p.P131L (on ENST00000292176; = p.P165L on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/590 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52692958; called by muse, mutect2, varscan2
- ZBTB8B | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 129/303 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1173120295; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 58/114 reads (51%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDHHC11 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52068813; called by muse, varscan2
- ZFP91 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.739); catalogued as rs1234668704, COSV99062528; called by muse, mutect2, varscan2
- ZFYVE19 | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215965232; called by muse, mutect2, varscan2
- ZNF10 | c.1391A>G p.H464R | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1481358765; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF174 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.557); catalogued as rs753184330, COSV51902673; called by muse, mutect2, varscan2
- ZNF226 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.155); catalogued as rs768371687, COSV56196094; called by muse, mutect2, varscan2
- ZNF275 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs782224594; called by muse, mutect2, varscan2
- ZNF30 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs199540599; called by muse, mutect2, varscan2
- ZNF423 | c.2783G>A p.R928H (on ENST00000563137 / NM_001379286.1; = p.R920H on NM_015069.4) | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs746868124, COSV52197695; called by muse, mutect2, varscan2
- ZNF43 | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs949997030; called by mutect2, varscan2
- ZNF514 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs767903159; called by muse, mutect2, varscan2
- ZNF536 | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 121/275 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV62821277; called by muse, mutect2, varscan2
- ZNF547 | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1568527425; called by muse, mutect2, varscan2
- ZNF615 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs768369772; called by muse, mutect2, varscan2
- ZNF791 | c.138del p.K46Nfs*18 | Frame Shift Del (DEL) | VAF 58/149 reads (39%) | catalogued as rs866339152, COSV58480817; called by mutect2, pindel, varscan2
- ZNF839 | c.1159A>G p.K387E (on ENST00000558850 / NM_001267827.1; = p.K503E on NM_018335.5) | Missense Mutation (SNP) | VAF 130/283 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51756799; called by muse, mutect2, varscan2
- A2M | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- AADAC | c.786del p.A263Pfs*30 | Frame Shift Del (DEL) | VAF 40/97 reads (41%) | called by mutect2, pindel, varscan2
- ABI1 | c.1447T>C p.W483R | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACACA | c.5051A>G p.H1684R | Missense Mutation (SNP) | VAF 191/445 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ACACB | c.4207C>A p.R1403S | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ACE | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 19/367 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACE | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 196/462 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ACVR1B | c.364_365del p.W122Gfs*28 | Frame Shift Del (DEL) | VAF 101/306 reads (33%) | called by pindel, varscan2
- ACVR2A | c.1310_1317delinsGAGGC p.K437_P439delinsRG | In Frame Del (DEL) | VAF 29/98 reads (30%) | called by pindel, varscan2*
- ADAM15 | c.2171G>C p.R724P | Missense Mutation (SNP) | VAF 114/534 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS17 | c.3121del p.R1041Afs*5 | Frame Shift Del (DEL) | VAF 33/77 reads (43%) | called by mutect2, pindel, varscan2
- ADAMTSL5 | c.1118del p.F373Sfs*55 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ADAMTSL5 | c.192-1G>T p.X64_splice | Splice Site (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- ADRA2C | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 211/465 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AEBP1 | c.513dup p.I172Hfs*34 | Frame Shift Ins (INS) | VAF 114/347 reads (33%) | called by mutect2, pindel, varscan2
- AFP | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- AHNAK | c.14625A>C p.E4875D | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AHNAK | c.13025A>C p.K4342T | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALDOB | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 160/395 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ALOX5 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 118/220 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ALPP | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 196/969 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, varscan2
- ALS2 | c.1533dup p.T512Hfs*36 | Frame Shift Ins (INS) | VAF 109/313 reads (35%) | called by mutect2, pindel, varscan2
- ANGEL2 | c.914G>A p.C305Y | Missense Mutation (SNP) | VAF 89/434 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK1 | c.5062A>C p.T1688P | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ANK1 | c.4588G>A p.A1530T | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.7759T>A p.F2587I | Missense Mutation (SNP) | VAF 47/624 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- ANKRD35 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD65 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.62); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ANO5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 156/317 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANXA7 | c.667del p.I223Lfs*13 (on ENST00000372919 / NM_001320880.2; = p.I201Lfs*13 on NM_001156.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 122/331 reads (37%) | called by mutect2, pindel, varscan2
- AOAH | c.1129A>G p.S377G | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AP2B1 | c.1156-1G>T p.X386_splice | Splice Site (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- APBA3 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1 | c.1895_1897del p.F632del | In Frame Del (DEL) | VAF 113/301 reads (38%) | called by mutect2, pindel, varscan2
- APOBEC3H | c.155del p.K52Sfs*51 | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | called by mutect2, pindel, varscan2
- AQP1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 255/543 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AQP7 | c.46del p.M16Wfs*6 | Frame Shift Del (DEL) | VAF 92/242 reads (38%) | called by mutect2, pindel, varscan2
- ARAF | c.1382A>G p.Q461R | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ARHGAP1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ARHGAP29 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP33 | c.2020del p.H674Ifs*14 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ARHGEF18 | c.84dup p.R29Qfs*11 | Frame Shift Ins (INS) | VAF 124/343 reads (36%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.4067C>T p.S1356L | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ARID1A | c.2296dup p.Q766Pfs*51 | Frame Shift Ins (INS) | VAF 55/151 reads (36%) | called by mutect2, pindel, varscan2
- ARID1A | c.3162_3163insAC p.Y1055Tfs*5 | Frame Shift Ins (INS) | VAF 99/235 reads (42%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1901del p.F634Sfs*4 | Frame Shift Del (DEL) | VAF 139/674 reads (21%) | called by mutect2, pindel, varscan2
- ASAP2 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ASPHD1 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 29/78 reads (37%) | called by mutect2, varscan2
- ATP13A1 | c.1442G>A p.C481Y | Missense Mutation (SNP) | VAF 130/298 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ATP2A1 | c.2069A>G p.Y690C | Missense Mutation (SNP) | VAF 248/511 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ATP2B4 | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 172/806 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ATR | c.1486_1488del p.V496del | In Frame Del (DEL) | VAF 48/114 reads (42%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.2519G>T p.R840M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- BACH2 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BAG4 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 145/521 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 67/170 reads (39%) | called by mutect2, varscan2
- BCL9 | c.4193dup p.Q1399Tfs*10 | Frame Shift Ins (INS) | VAF 54/332 reads (16%) | called by mutect2, pindel, varscan2
- BCOR | c.2630C>T p.T877I | Missense Mutation (SNP) | VAF 135/341 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BICRAL | c.1075A>G p.M359V | Missense Mutation (SNP) | VAF 169/414 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- BIRC6 | c.13875C>A p.C4625* | Nonsense Mutation (SNP) | VAF 99/198 reads (50%) | called by muse, mutect2, varscan2
- BMPER | c.495C>T p.G165= | Splice Region (SNP) | VAF 124/331 reads (37%) | called by muse, mutect2, varscan2
- BNC1 | c.1660G>C p.A554P | Missense Mutation (SNP) | VAF 190/452 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BORA | c.1005del p.K335Nfs*7 (on ENST00000613797; = p.K260Nfs*7 on NM_024808.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 57/156 reads (37%) | called by mutect2, pindel, varscan2
- BORCS6 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 217/460 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPNT2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 200/473 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BRAP | c.1087C>A p.H363N | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- BRD9 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- BSN | c.8809A>G p.K2937E | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- C11orf95 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- C1orf115 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 147/643 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- C2 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 244/584 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- C2CD5 | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C4orf47 | c.317dup p.P107Afs*55 | Frame Shift Ins (INS) | VAF 43/136 reads (32%) | called by mutect2, pindel, varscan2
- CACNA1A | c.6266C>T p.P2089L | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CACNA1D | c.279del p.K93Nfs*30 | Frame Shift Del (DEL) | VAF 40/379 reads (11%) | called by mutect2, pindel, varscan2
- CACNA1F | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- CACNA1G | c.4323C>A p.C1441* | Nonsense Mutation (SNP) | VAF 59/211 reads (28%) | called by muse, mutect2, varscan2
- CACNA1I | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 143/340 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- CACNA2D1 | c.1148G>C p.R383P | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNA2D4 | c.1630G>T p.A544S | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2
- CADM3 | c.395A>G p.K132R (on ENST00000368125 / NM_001127173.3; = p.K166R on NM_021189.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.414); called by muse, varscan2
- CAMK1G | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CASP6 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CASZ1 | c.1564C>A p.L522M | Missense Mutation (SNP) | VAF 135/295 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CATSPER1 | c.1073del p.G358Afs*6 | Frame Shift Del (DEL) | VAF 178/496 reads (36%) | called by mutect2, pindel, varscan2
- CBX4 | c.690del p.N231Tfs*3 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by pindel, varscan2
- CCDC102A | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC171 | c.2075dup p.N692Kfs*9 | Frame Shift Ins (INS) | VAF 21/52 reads (40%) | called by mutect2, varscan2
- CCDC174 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCNT2 | c.893A>C p.N298T | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCSAP | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 81/405 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CCSER2 | c.1382G>C p.S461T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CDH19 | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CDH3 | c.45+8A>G | Splice Region (SNP) | VAF 225/563 reads (40%) | called by muse, mutect2, varscan2
- CDH4 | c.432del p.S145Lfs*20 | Frame Shift Del (DEL) | VAF 80/183 reads (44%) | called by mutect2, pindel, varscan2
- CDH7 | c.456del p.K152Nfs*24 | Frame Shift Del (DEL) | VAF 66/186 reads (35%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.5380T>C p.Y1794H | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CELSR1 | c.8278G>A p.A2760T | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.217); called by muse, mutect2
- CELSR1 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CELSR3 | c.6569T>C p.L2190P | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CEMIP | c.629A>T p.Y210F | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CENPF | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 134/307 reads (44%) | called by mutect2, varscan2
- CEP78 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CFAP100 | c.1345_1347del p.K449del | In Frame Del (DEL) | VAF 62/153 reads (41%) | called by mutect2, pindel, varscan2
- CFAP298-TCP10L | c.1024dup p.M342Nfs*9 | Frame Shift Ins (INS) | VAF 56/139 reads (40%) | called by mutect2, pindel, varscan2
- CFAP52 | c.1248del p.H416Qfs*26 | Frame Shift Del (DEL) | VAF 84/214 reads (39%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4387A>G p.K1463E | Missense Mutation (SNP) | VAF 178/402 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CFD | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHAD | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHADL | c.2175G>T p.W725C | Missense Mutation (SNP) | VAF 211/441 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CHD3 | c.1617_1618del p.R540Sfs*46 | Frame Shift Del (DEL) | VAF 130/376 reads (35%) | called by pindel, varscan2
- CHD7 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); called by muse, varscan2
- CHRNE | c.345-3C>T | Splice Region (SNP) | VAF 158/368 reads (43%) | called by muse, mutect2, varscan2
- CIC | c.2708T>C p.V903A | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CIPC | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.019); called by muse, mutect2
- CKMT2 | c.1235del p.P412Lfs*40 | Frame Shift Del (DEL) | VAF 77/223 reads (35%) | called by mutect2, pindel, varscan2
- CLCA2 | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN2 | c.1814A>G p.H605R | Missense Mutation (SNP) | VAF 132/281 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.07); called by muse, varscan2
- CLMN | c.2255dup p.N752Kfs*2 | Frame Shift Ins (INS) | VAF 101/252 reads (40%) | called by mutect2, pindel, varscan2
- CLTC | c.3571A>G p.N1191D | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CNIH3 | c.445_447del p.Y149del | In Frame Del (DEL) | VAF 54/254 reads (21%) | called by pindel, varscan2
- CNN2 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CNOT3 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNTN5 | c.959T>C p.M320T | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- COL12A1 | c.5627T>C p.L1876P | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- COPS3 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COQ5 | c.965A>G p.H322R | Missense Mutation (SNP) | VAF 199/472 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CR1 | c.913C>T p.H305Y (on ENST00000367051; = p.H755Y on NM_000651.6) | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CRMP1 | c.1461+2T>C p.X487_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- CRYBG3 | c.925dup p.T309Nfs*12 | Frame Shift Ins (INS) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- CSF1 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSRP2 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CTDSP1 | c.511del p.A171Pfs*19 | Frame Shift Del (DEL) | VAF 53/116 reads (46%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.322del p.L108Sfs*65 | Frame Shift Del (DEL) | VAF 129/390 reads (33%) | called by mutect2, pindel, varscan2
- CYP2A7 | c.974-2A>G p.X325_splice | Splice Site (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- CYP4F11 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CYP4F2 | c.1302G>T p.W434C | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DAP3 | c.456A>G p.I152M | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DAZAP1 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DDIAS | c.2477del p.N826Ifs*2 | Frame Shift Del (DEL) | VAF 49/145 reads (34%) | called by mutect2, pindel, varscan2
- DEDD2 | c.957del p.R320Gfs*34 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | called by mutect2, pindel, varscan2
- DENND1B | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- DENND4C | c.3649T>C p.S1217P (on ENST00000434457 / NM_001330640.2; = p.S1168P on NM_017925.7) | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND5B | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEPDC5 | c.2891_2892del p.S964Cfs*96 (on ENST00000400246; = p.S1033Cfs*96 on NM_014662.5) | Frame Shift Del (DEL) | VAF 105/390 reads (27%) | called by pindel, varscan2
- DHRS12 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.2844del p.C949Afs*55 | Frame Shift Del (DEL) | VAF 59/149 reads (40%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 157/396 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DLL1 | c.1222T>G p.Y408D | Missense Mutation (SNP) | VAF 259/540 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DMGDH | c.2596dup p.T866Nfs*53 | Frame Shift Ins (INS) | VAF 104/272 reads (38%) | called by mutect2, pindel, varscan2
- DMKN | c.301del p.E101Kfs*86 | Frame Shift Del (DEL) | VAF 78/665 reads (12%) | called by mutect2, pindel, varscan2
- DMP1 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 298/651 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DMPK | c.1292C>A p.P431Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- DMRTC1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAH2 | c.6826G>T p.V2276L | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DNAH9 | c.9455dup p.A3153Gfs*2 | Frame Shift Ins (INS) | VAF 99/266 reads (37%) | called by mutect2, pindel, varscan2
- DNAJC21 | c.255C>A p.S85R | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DPPA4 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 127/265 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DSC1 | c.1907dup p.N636Kfs*3 | Frame Shift Ins (INS) | VAF 37/108 reads (34%) | called by mutect2, pindel
- DSG1 | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 167/389 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DST | c.1447G>A p.V483M (on ENST00000361203 / NM_001374722.1; = p.V157M on NM_001723.6) | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- DST | c.1322del p.L441Yfs*5 (on ENST00000361203 / NM_001374722.1; = p.L115Yfs*5 on NM_001723.6) | Frame Shift Del (DEL) | VAF 71/177 reads (40%) | called by mutect2, pindel, varscan2
- DSTYK | c.2303T>C p.L768P | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.9019C>T p.R3007* | Nonsense Mutation (SNP) | VAF 208/494 reads (42%) | called by muse, mutect2, varscan2
- DYTN | c.1544T>A p.I515N | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- E2F8 | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB5 | c.2900G>A p.R967K | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EFCAB8 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- EMD | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 154/383 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EQTN | c.49del p.S17Vfs*4 | Frame Shift Del (DEL) | VAF 41/137 reads (30%) | called by mutect2, pindel, varscan2
- ERMAP | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERN1 | c.910del p.V304Lfs*30 | Frame Shift Del (DEL) | VAF 49/156 reads (31%) | called by mutect2, pindel, varscan2
- ETNK2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVPL | c.5375T>C p.I1792T | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- EXOC3L4 | c.1701+2T>C p.X567_splice | Splice Site (SNP) | VAF 65/144 reads (45%) | called by muse, mutect2, varscan2
- FAM155B | c.715G>C p.A239P | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM160A1 | c.1923T>G p.D641E | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- FAM160B2 | c.2225A>G p.Q742R | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM184A | c.833A>G p.Q278R | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAM216A | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); called by muse, varscan2
- FAM81B | c.937A>G p.N313D | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- FAM83E | c.889del p.Q297Rfs*6 | Frame Shift Del (DEL) | VAF 108/275 reads (39%) | called by mutect2, pindel, varscan2
- FAM83H | c.1094del p.G365Afs*180 | Frame Shift Del (DEL) | VAF 110/259 reads (42%) | called by mutect2, pindel, varscan2
- FAT4 | c.12553T>C p.W4185R | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBN2 | c.7800_7801del p.G2602Vfs*4 | Frame Shift Del (DEL) | VAF 178/462 reads (39%) | called by mutect2, pindel, varscan2
- FBXO21 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FBXO27 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- FBXW8 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL6 | c.511A>T p.K171* | Nonsense Mutation (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- FGB | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.861); called by muse, mutect2
- FGFRL1 | c.786del p.T263Pfs*12 | Frame Shift Del (DEL) | VAF 92/218 reads (42%) | called by mutect2, pindel, varscan2
- FLG2 | c.3458A>G p.Y1153C | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FMN2 | c.5044C>T p.L1682F | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FMNL1 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOLH1 | c.586T>C p.C196R | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- FOS | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXA2 | c.468dup p.H157Afs*82 (on ENST00000377115 / NM_153675.3; = p.H163Afs*82 on NM_021784.5) | Frame Shift Ins (INS) | VAF 120/340 reads (35%) | called by mutect2, pindel, varscan2
- FOXA3 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 179/367 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- FRAS1 | c.2129T>C p.I710T | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FRMD4A | c.2890C>A p.Q964K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FRMPD3 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.044); called by muse, mutect2
- FRY | c.3820T>C p.Y1274H | Missense Mutation (SNP) | VAF 165/369 reads (45%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FSIP2 | c.2950A>G p.R984G | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FSIP2 | c.15874C>T p.L5292F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FTSJ1 | c.704_705insG p.F235Lfs*11 | Frame Shift Ins (INS) | VAF 143/388 reads (37%) | called by mutect2, pindel, varscan2
- FUCA1 | c.178del p.V60Cfs*73 | Frame Shift Del (DEL) | VAF 170/466 reads (36%) | called by mutect2, pindel, varscan2
- FYCO1 | c.3518A>G p.D1173G | Missense Mutation (SNP) | VAF 185/459 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FYCO1 | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- GAD2 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- GAREM2 | c.2055del p.S686Pfs*88 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- GBA | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 297/1162 reads (26%) | called by muse, mutect2, varscan2
- GCLC | c.685G>T p.A229S (on ENST00000643939; = p.A227S on NM_001498.4) | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GDNF | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- GLIS3 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLRA2 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLT1D1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLT8D2 | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GMPS | c.392T>G p.I131S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GOLGA2 | c.2728dup p.Q910Pfs*11 | Frame Shift Ins (INS) | VAF 88/237 reads (37%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); called by muse, varscan2
- GP2 | c.1240A>G p.K414E (on ENST00000381362 / NM_001007240.3; = p.K411E on NM_001502.4) | Missense Mutation (SNP) | VAF 92/165 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GPATCH4 | c.802A>G p.N268D | Missense Mutation (SNP) | VAF 85/424 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR101 | c.901A>G p.R301G | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPRC5C | c.1412A>G p.K471R (on ENST00000652232; = p.K426R on NM_018653.4) | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRAMD1B | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK5 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GTF3C1 | c.4083+1del p.X1361_splice | Splice Site (DEL) | VAF 53/146 reads (36%) | called by mutect2, pindel, varscan2
- GTPBP1 | c.63del p.E22Sfs*46 | Frame Shift Del (DEL) | VAF 56/120 reads (47%) | called by mutect2, pindel, varscan2
1,003 further variants in this file (426 protein-altering or splice-affecting, 336 silent, 241 other) are not listed here.
